Gene-level copy-number profile of tumor specimen TCGA-02-0024-01B from TCGA case TCGA-02-0024, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 35.9 years (13,116 days).
Specimen TCGA-02-0024-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8ffe7976-b09b-42e3-8b4a-11bceb45735c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0024-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9eeea619-2074-4f80-8b48-15c27a39a908

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 80; copy number 2: 7,035; copy number 3: 11,730; copy number 4: 35,059; copy number 5: 3,119; copy number 6: 2,639; copy number 13: 10; copy number 14: 20; copy number 17: 49; copy number 23: 5; copy number 34: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0024-01): tumor purity 0.79, ploidy 3.81, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,512,115–23,438,700, 26 genes (within-gene range 0–2): MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 129 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 1 gene, copy number 23 (within-gene range 4–34): AC058822.1.
- chr4:53,592,956–55,905,086, 49 genes, copy number 23–34: LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1.
- chr7:64,582,733–64,950,701, 20 genes, copy number 14: AC016769.2, AC016769.4, AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3.
- chr7:116,672,196–118,004,045, 40 genes, copy number 17: MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1.
- chr7:120,273,175–121,845,131, 19 genes, copy number 13–17 (within-gene range 3–17): KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2.

Autosomal genes at a single copy (total copy number 1): 80. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
